Surgical pathology report (de-identified scan), TCGA case TCGA-N8-A4PO, project TCGA-UCS (Uterine Carcinosarcoma), tissue source site University of North Carolina, specimen TCGA-N8-A4PO-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REVISED REPORT

Case Number :

ICD0-3
Carcinosarcoma, NA
8980/3
Site: Uterine,
Lower Segment
12-14-12
C54.2

Diagnosis:

A: Cervix, posterior, removal

- Cervix with small focus of glandular tissue suspicious for carcinoma

- No squamous mucosa identified

B: Uterus, cervix, bilateral tubes and ovaries, total abdominal hysterectomy and bilateral salpingo-oophorectomy

Uterus and cervix, hysterectomy:

Location of tumor: lower uterine segment/cervix

Histologic type: carcinosarcoma with heterologous elements, see comment

Stromal invasion: Inner half

Depth: 3mm Wall thickness: 9mm Percent: 33%

Serosal involvement: not identified

Lower uterine segment involvement: present

Cervical involvement: present

Adnexal involvement (see below): not identified

Cervical/vaginal margin and distance: tumor is 1.7 cm from the ectocervical margin

Lymphovascular space invasion: not identified

Other pathologic findings: leiomyoma, 0.4 cm

Tumor estrogen receptor and progesterone receptor immunohistochemistry results: Pending, will be reported in an addendum

AJCC Pathologic Stage: pT2 pNx

FIGO (2008 classification) Stage grouping: II

These stages are based on information available at the time of this report, and are subject to change pending additional

[page 2 of 4]
information and clinical review.

Ovaries:

- Benign with simple cysts and corpora albicantia

Fallopian tubes:

- Benign fallopian tubes

Comment:

The tumor exhibits carcinomatous and sarcomatous differentiation, with heterologous cartilaginous differentiation, and homologous differentiation consistent with endometrial stromal sarcoma. The tumor is staged as a pT2 since there is lower uterine segment and cervical involvement.

Clinical History:

-year-old with endometrial cancer.

Gross Description:

Specimen A is received in a formalin-filled container labeled "posterior cervix" and consists of a 2.6 x 1.0 x 0.7 cm fragment of rubbery tan/gray tissue. One surface is lined by a focally erythematous mucosa. The opposite surface (stroma) is inked black and the specimen is trisected and submitted in A1 and A2,

Specimen B is labeled "uterus, cervix, bilateral tubes and ovaries" and consists of a 72 gram (8.1 x 4.3 x 3.6 cm) uterus with attached left ovary (2.5 x 1.6 x 1.0 cm), left fimbriated fallopian tube (4.1 cm long x 0.4 cm in diameter), right ovary (2.7 x 1.7 x 1.0 cm) and right fimbriated fallopian tube (4.4 cm long x 0.4 cm in diameter).

The endometrial cavity is 2.5 cm wide x 3.6 cm long and has a 3.6 x 3.1 x 1.7 cm irregularly shaped gray/white fungating mass at the anterior lower uterine segment. This mass extends into the endocervical canal, 1.0 cm from the external os. The mass is smooth and white on cut surface, extends 0.1 cm into a 1.1 cm thick stroma. The posterior cavity is uninvolved by mass. In place is a 13.5 x 0.3 x 0.2 cm white serpentine intrauterine device. The endometrium is red/brown, smooth (<0.1 cm thick). The myometrium is 2.3 cm thick, trabeculated with a single homogeneous white whorled rubbery nodule (0.4 x 0.3 x 0.3 cm). The left ovary and two parenchymal simple cysts up to 1.2 x 1.0

[page 3 of 4]
x 0.9 cm in greatest dimension each filled with a clear thin fluid. The left fallopian tube, right ovary and right fallopian tube are all unremarkable. Also within the specimen container are 2 fragments of tan-brown nodular tissue measuring 4.5 x 4.5 x 3.2 cm in aggregate.

Inking: anterior cervix/blue, posterior cervix/black. Tumor was given to tissue procurement foundation.

Block Summary:

- B1 - Anterior cervix with mass
- B2 - Perpendicular of anterior lower uterine segment with mass, one piece bisected
- B3-B4 - Additional sections of mass
- B5 - Posterior cervix
- B6 - Perpendicular posterior lower uterine segment
- B7 - Anterior corpus with intramural nodule, one piece bisected
- B8 - Posterior corpus
- B9 - Left ovary
- B10 - Left fallopian tube
- B11 - Right ovary
- B12 - Right fallopian tube
- B13-B14 - Full length of full thickness perpendicular anterior cervix with anterior lower uterine segment, one piece bisected (B13 is anterior cervix, B14 is anterior lower uterine segment)
- B15-B17 - Perpendicular sections of posterior cervix
- B18-B19 - Sections from the separate aggregate of mass

Light Microscopy:

Light microscopic examination performed by Dr.

Procedures/Addenda:

Addendum

Addendum

Addendum specimen B: Estrogen receptor and progesterone receptor immunohistochemical stains were performed on the carcinosarcoma tumor cells (slide B18).

Estrogen receptor: negative in tumor cells

Progesterone receptor: scattered positivity (1-2+) in <10% of cells

[page 4 of 4]
For cases in which immunostains are performed, the following applies:

Appropriate internal and/or external positive and negative controls have been evaluated. Some of the immunohistochemical reagents used in this case may be classified as analyte specific reagents (ASR). These were developed and have performance characteristics determined by . These reagents have not been cleared or approved by the US Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA-88) as qualified to perform high complexity clinical laboratory testing.

12/13/12

	Yes	No
Compliance		X
Quality		X
Proficiency		X
Other		

KMI

Source: NCI Genomic Data Commons file 88a334f5-044f-47df-a68d-628af809dfff (TCGA-N8-A4PO.E13D4B38-F4E5-41EB-A590-087C97EA4DEA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).